Somatic mutation profile of tumor specimen C3N-02786-02 (aliquot CPT0206230006) from CPTAC case C3N-02786, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 40.0 years (14,593 days).
Specimen C3N-02786-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c66129f-4aaf-4a19-9511-e1e781f479e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02786-71 (Blood Derived Normal), aliquot CPT0206280002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/83270754-1264-4227-9e8d-c2ce13782087

The open-access MAF lists 37 somatic variants for this specimen: 22 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 13, Splice Site 3, 3'UTR 1, Frame Shift Ins 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS16 | c.1889G>A p.R630H | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs377507889; called by muse, mutect2
- ATRX | c.6332G>T p.R2111L | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64875280; called by muse, mutect2, varscan2
- BCOR | c.2287C>T p.R763W | Missense Mutation (SNP) | VAF 111/525 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs780348147; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CREB3L3 | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 51/246 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV50211734; called by muse, mutect2, varscan2
- DTX2 | c.1145T>C p.V382A | Missense Mutation (SNP) | VAF 57/477 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs1365795659; called by muse, mutect2, varscan2
- KRT73 | c.157G>T p.G53C | Missense Mutation (SNP) | VAF 190/700 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as rs1181710985; called by muse, mutect2, varscan2
- RNF216 | c.1382G>A p.R461Q (on ENST00000425013 / NM_207116.3; = p.R518Q on NM_207111.4) | Missense Mutation (SNP) | VAF 33/223 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.271); catalogued as rs778183712, COSV66290460; called by muse, mutect2, varscan2
- APC2 | c.5359G>C p.V1787L | Missense Mutation (SNP) | VAF 41/187 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- CFH | c.1085A>G p.E362G | Missense Mutation (SNP) | VAF 79/368 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- DEFB112 | c.236A>T p.K79M | Missense Mutation (SNP) | VAF 64/159 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- IQSEC3 | c.2810-1G>T p.X937_splice (on ENST00000538872 / NM_001170738.2; = p.X634_splice on NM_015232.1) | Splice Site (SNP) | VAF 34/166 reads (20%) | called by muse, mutect2, varscan2
- ITSN2 | c.3323C>T p.P1108L | Missense Mutation (SNP) | VAF 48/256 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MUC16 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MUC17 | c.1474T>C p.S492P | Missense Mutation (SNP) | VAF 14/412 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.262); called by muse, mutect2
- NPR1 | c.3077A>T p.E1026V | Missense Mutation (SNP) | VAF 65/323 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- NUTM1 | c.3209C>A p.A1070D | Missense Mutation (SNP) | VAF 64/209 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- PTPRR | c.181dup p.I61Nfs*5 | Frame Shift Ins (INS) | VAF 98/475 reads (21%) | called by mutect2, pindel, varscan2
- RB1 | c.1512_1513del p.N505Sfs*2 | Frame Shift Del (DEL) | VAF 17/68 reads (25%) | called by mutect2, pindel, varscan2
- RB1CC1 | c.-167+1G>T | Splice Site (SNP) | VAF 39/116 reads (34%) | called by muse, mutect2, varscan2
- SYTL5 | c.1062+1G>T p.X354_splice | Splice Site (SNP) | VAF 21/108 reads (19%) | called by muse, mutect2, varscan2
- TJP1 | c.4867G>A p.E1623K | Missense Mutation (SNP) | VAF 57/207 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- ZNF492 | c.666G>T p.K222N | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- ARL6IP4 | c.939G>A p.A313= (on ENST00000315580 / NM_018694.3; = p.A294= on NM_016638.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/158 reads (22%) | catalogued as rs773998680, COSV54901422; called by muse, varscan2
- CCDC74A | c.120G>A p.Q40= | Silent (SNP) | VAF 58/335 reads (17%) | catalogued as COSV54605205; called by muse, mutect2, varscan2
- CES2 | c.939G>A p.V313= | Silent (SNP) | VAF 77/267 reads (29%) | called by muse, mutect2, varscan2
- DMD | c.10911G>A p.S3637= | Silent (SNP) | VAF 114/554 reads (21%) | catalogued as rs747939733; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- ELFN2 | c.219C>A p.S73= | Silent (SNP) | VAF 36/342 reads (11%) | called by mutect2, varscan2
- H3C11 | c.69C>G p.T23= | Silent (SNP) | VAF 90/252 reads (36%) | called by muse, mutect2, varscan2
- KIF18A | c.1911C>T p.T637= | Silent (SNP) | VAF 76/274 reads (28%) | catalogued as COSV54185060; called by muse, mutect2, varscan2
- LPA | c.3639C>T p.T1213= | Silent (SNP) | VAF 82/300 reads (27%) | called by muse, mutect2, varscan2
- PCSK6 | c.204C>G p.P68= | Silent (SNP) | VAF 32/136 reads (24%) | catalogued as rs1462684341; called by muse, mutect2, varscan2
- SHANK2 | c.4890C>A p.I1630= | Silent (SNP) | VAF 85/271 reads (31%) | catalogued as COSV53605866; called by muse, mutect2, varscan2
- TMEM161A | c.102C>T p.N34= | Silent (SNP) | VAF 93/388 reads (24%) | catalogued as rs538146991; called by muse, mutect2, varscan2
- TMUB1 | c.222G>A p.L74= | Silent (SNP) | VAF 17/89 reads (19%) | called by muse, mutect2, varscan2
- VIRMA | c.5361C>T p.S1787= | Silent (SNP) | VAF 55/203 reads (27%) | catalogued as rs779033259, COSV52591121; called by muse, mutect2, varscan2
- AC114490.3 | c.*855G>A | 3'UTR (SNP) | VAF 131/575 reads (23%) | called by muse, mutect2, varscan2
- FUS | c.833-36C>T | Intron (SNP) | VAF 63/262 reads (24%) | called by muse, mutect2, varscan2
